Gene-level copy-number profile of specimen HCM-CSHL-0859-C22-85A from HCMI case HCM-CSHL-0859-C22, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Intrahepatic bile duct; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 62.9 years (22,982 days).
Specimen HCM-CSHL-0859-C22-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 19.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 167fcef0-a148-4e3f-9607-8a6f544634c3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0859-C22-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,711 have no estimate.
https://portal.gdc.cancer.gov/files/1bdd264a-1d94-467a-b261-9898737003ed

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 752; copy number 2: 13,202; copy number 3: 23,800; copy number 4: 20,271; copy number 5: 219; copy number 6: 510; copy number 7: 7; copy number 8: 39; copy number 9: 1; copy number 10: 28; copy number 11: 53; copy number 12: 2; copy number 13: 1; copy number 14: 15; copy number 17: 10; copy number 18: 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 158 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:40,699,066–40,862,626, 3 genes, copy number 12–13: HMGN2P24, AC099560.1, AC099560.2.
- chr3:41,162,287–42,225,890, 15 genes, copy number 14: AC009743.1, MRPS31P1, CTNNB1, ULK4, AC099537.1, RN7SKP58, ATP6V0E1P2, Y_RNA, U8, RPL36P20, GEMIN2P2, TRAK1, AC093414.1, TPMTP2, RNU4-78P.
- chr3:86,481,943–86,817,036, 2 genes, copy number 18: LINC02070, AC108706.1.
- chr3:87,051,192–87,276,584, 5 genes, copy number 7: PPATP1, LINC00506, MIR4795, CHMP2B, POU1F1.
- chr3:87,594,838–88,319,022, 12 genes, copy number 8–17: APOOP2, PSMC1P6, AC108749.1, RNU6-873P, HTR1F, RNU6ATAC6P, CGGBP1, AC119733.1, ZNF654, CBX5P1, C3orf38, ABCF2P1.
- chr6:41,736,711–43,620,523, 79 genes, copy number 8–11 (within-gene range 5–11) (broad region; genes not listed).
- chr6:46,159,185–47,832,780, 29 genes, copy number 9–10: ENPP5, ACTG1P9, RCAN2, AL359633.1, AL035670.1, CYP39A1, SLC25A27, AL591242.1, TDRD6, PLA2G7, ANKRD66, AL161618.1, MEP1A, ADGRF5, ADGRF5-AS1, ADGRF1, TNFRSF21, B3GNTL1P2, AL355353.1, CD2AP, Y_RNA, AL358178.1, ADGRF2, ADGRF4, RN7SKP116, AL356421.2, AL356421.1, OPN5, RNU1-105P.
- chr9:61,190,003–61,662,690, 11 genes, copy number 8: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA, AL935212.1.
- chr10:56,357,227–56,361,273, 1 gene, copy number 7: ZWINT.
- chr19:24,004,358–24,004,507, 1 gene, copy number 7: RNA5-8SP4.

Autosomal genes at a single copy (total copy number 1): 752. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
